CCDI case PBBTEC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/17c1f75c-54f4-4826-adfc-b08fa3377a6d

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 7.1 years (2,587 days).

Biospecimens (4 samples)
- Sample 0DGB94: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DGB9P, 0DGBAF (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGFVW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
